Somatic mutation profile of tumor specimen BLGSP-71-08-00053-01A (aliquot BLGSP-71-08-00053-01A-01D-A671-33) from CGCI case BLGSP-71-08-00053, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 9.1 years (3,324 days).
Specimen BLGSP-71-08-00053-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65cc9a89-aa20-4f04-adb2-597f77b57e1b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00053-10A (Blood Derived Normal), aliquot BLGSP-71-08-00053-10A-01D-A671-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8521f2d2-c01c-4934-8bfe-706d1a5b62ea

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 3, 5'UTR 2, Silent 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 240/441 reads (54%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 39/50 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 43/49 reads (88%) | catalogued as COSV104433609; called by muse, mutect2, varscan2
- ID3 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65800754, COSV65801030, COSV65801279; called by muse, varscan2
- ID3 | c.144C>G p.Y48* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV101000736, COSV65800991, COSV65801035; called by muse, varscan2
- ZFP36L2 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs1470276604; called by muse, mutect2, varscan2
- GNA13 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYC | c.1103A>G p.N368S (on ENST00000377970; = p.N383S on NM_002467.6) | Missense Mutation (SNP) | VAF 331/631 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFX7 | c.703_704del p.K235Vfs*11 (on ENST00000559447 / NM_001368074.1; = p.K332Vfs*11 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 93/248 reads (38%) | called by mutect2, pindel, varscan2
- USH2A | c.11689A>G p.I3897V | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- MYC | c.156A>G p.K52= (on ENST00000377970; = p.K67= on NM_002467.6) | Silent (SNP) | VAF 108/210 reads (51%) | called by muse, varscan2
- MYC | c.-406C>G | 5'UTR (SNP) | VAF 10/41 reads (24%) | catalogued as COSV104388369; called by muse, mutect2, varscan2
- MYC | c.-309G>C | 5'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as COSV104388184, COSV104388185, COSV104388603; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58332313 G>A | 5'Flank (SNP) | VAF 45/133 reads (34%) | called by muse, mutect2, varscan2
